Gene-level copy-number profile of tumor specimen MP2PRT-PAUGEZ-TMP1-A from MP2PRT case MP2PRT-PAUGEZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,809 days).
Specimen MP2PRT-PAUGEZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file de383eb3-1980-4a12-96b1-cb0e06f34fc6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUGEZ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/aeddeb15-afc3-4c11-8170-e63923ed2d7f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 117; copy number 2: 40,709; copy number 3: 15,764; copy number 4: 1,008; copy number 5: 76; copy number 6: 48; copy number 7: 431; copy number 8: 226; copy number 9: 3; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,176,328–89,234,912, 7 genes (within-gene range 0–1): IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr7:38,256,337–38,256,396, 1 gene (within-gene range 0–2): TRGJP2.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–3): TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 786 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:21,756,548–37,544,701, 260 genes, copy number 5–7 (broad region; genes not listed).
- chr10:53,766,400–60,741,828, 49 genes, copy number 5–6: AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT.
- chr10:61,901,684–87,845,612, 477 genes, copy number 6–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
